FM case AD2702 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/d2433afd-75b5-4db9-a78c-bb912a687c45

Male, 55.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the esophagus; metastasis biopsied or resected from the adrenal gland. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
